Gene-level copy-number profile of tumor specimen ALCH-B49U-TTP1-A from ALCHEMIST case ALCH-B49U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.7 years (21,074 days).
Specimen ALCH-B49U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45d631e5-617f-4fa9-9d2f-0c38a3c8d4cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B49U-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/ec2b6f43-7917-45ce-8d86-d4d335181002

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 574; copy number 1: 8,002; copy number 2: 45,628; copy number 3: 4,541; copy number 4: 135; copy number 5: 4; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,532,166–46,570,255, 3 genes (within-gene range 0–2): TMEM275, MKNK1-AS1, KNCN.
- chr2:95,274,449–95,416,616, 5 genes: PROM2, KCNIP3, FABP7P2, FAHD2A, AC009238.3.
- chr9:35,104,112–35,116,341, 1 gene: FAM214B.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–2): NEK6, AL162724.2, AL162724.1.
- chr10:32,231,849–32,232,245, 1 gene: RPS24P13.
- chr11:73,395,559–73,396,436, 1 gene (within-gene range 0–1): AP000763.4.
- chr13:110,641,412–110,713,603, 1 gene (within-gene range 0–2): CARS2.
- chr15:25,180,497–25,257,027, 40 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr17:61,361,668–61,485,110, 7 genes (within-gene range 0–2): AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 6: RPL23AP88.
- chr7:155,611,231–155,781,485, 2 genes, copy number 5: AC009403.1, RBM33.
- chr19:1,086,574–1,106,791, 2 genes, copy number 5 (within-gene range 2–5): POLR2E, GPX4.

Autosomal genes at a single copy (total copy number 1): 5,658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
